Somatic mutation profile of tumor specimen C3N-04162-03 (aliquot CPT0222730006) from CPTAC case C3N-04162, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 46.8 years (17,099 days).
Specimen C3N-04162-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab478dee-7249-45f1-a8a8-5d1ed5d42c1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04162-71 (Blood Derived Normal), aliquot CPT0222830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc287e0f-587d-47b5-827b-ce3dd63e1f13

The open-access MAF lists 318 somatic variants for this specimen: 216 protein-altering or splice-affecting, 73 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 188, Silent 73, Nonsense Mutation 16, Intron 12, RNA 8, Splice Site 5, 5'Flank 4, 3'UTR 3, Frame Shift Del 3, Frame Shift Ins 3, 5'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 403/688 reads (59%) | hotspot (GDC flag); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.3628C>T p.R1210* | Nonsense Mutation (SNP) | VAF 68/146 reads (47%) | catalogued as rs1467625872; called by muse, mutect2, varscan2
- ADGRL3 | c.905G>C p.R302P (on ENST00000506720 / NM_001322402.2; = p.R234P on NM_015236.6) | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72266433; called by muse, mutect2, varscan2
- AFAP1L2 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs540007841, COSV58415352; called by muse, mutect2, varscan2
- AGBL1 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs770812651; called by muse, mutect2, varscan2
- ANGPTL3 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs753754473, COSV51995766; called by muse, mutect2
- B3GLCT | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 56/426 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.196); catalogued as rs144207959; called by muse, mutect2, varscan2
- C2orf80 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs377540865, COSV58015382; called by muse, mutect2, varscan2
- CANT1 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1393793538; called by muse, mutect2, varscan2
- CDKN2A | c.327del p.W110Gfs*36 | Frame Shift Del (DEL) | VAF 261/701 reads (37%) | catalogued as COSV58723784; called by mutect2, pindel, varscan2
- CFHR1 | c.926G>T p.R309L | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.293); catalogued as COSV57627059; called by muse, mutect2, varscan2
- CHST6 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 262/860 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.175); catalogued as COSV59999976; called by muse, mutect2, varscan2
- CKAP2L | c.1266G>C p.L422F | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV100198540; called by muse, mutect2, varscan2
- CMTM7 | c.304G>T p.V102L | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV58549868; called by muse, mutect2, varscan2
- COL3A1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs547373542; called by muse, mutect2, varscan2
- CPN1 | c.1030G>A p.G344R | Missense Mutation (SNP) | VAF 96/308 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64942728; called by muse, mutect2, varscan2
- CPSF1 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 51/349 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs782533294, COSV100574703; called by muse, mutect2, varscan2
- CRACD | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT tolerated (0.58); PolyPhen benign (0.028); catalogued as rs368076623; called by muse, mutect2, varscan2
- CRY1 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as rs1417804049; called by muse, mutect2, varscan2
- CSMD3 | c.7955C>A p.T2652K (on ENST00000297405 / NM_001363185.1; = p.T2548K on NM_052900.3) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52186438, COSV52276704, COSV99835151; called by muse, mutect2, varscan2
- CUL3 | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52361183, COSV52363524; called by muse, mutect2, varscan2
- DLGAP3 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as COSV52392908; called by muse, mutect2, varscan2
- DNAI2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.177); catalogued as rs752440806, COSV56761525; called by muse, mutect2, varscan2
- DOCK2 | c.3598C>T p.R1200C | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV56958660, COSV56967914; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs889334921; called by muse, mutect2, varscan2
- EVC2 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as rs1162069166; called by muse, mutect2, varscan2
- F2RL3 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 58/541 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749245732; called by muse, mutect2, varscan2
- FAM13A | c.2213G>A p.R738Q | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs145527843; called by muse, mutect2, varscan2
- FAM222A | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 144/471 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs542271980; called by muse, mutect2, varscan2
- FRS2 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs187299511; called by muse, mutect2, varscan2
- GDPD4 | c.823C>G p.L275V | Missense Mutation (SNP) | VAF 124/235 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60023847; called by muse, mutect2, varscan2
- GLT1D1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as rs768702559; called by muse, mutect2, varscan2
- GOLGA8J | c.79A>G p.R27G | Missense Mutation (SNP) | VAF 69/387 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1260638807; called by muse, mutect2, varscan2
- GRK2 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.061); catalogued as rs1356953611; called by muse, mutect2, varscan2
- GTF3C1 | c.4996G>A p.D1666N | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236375622; called by muse, mutect2
- H1-5 | c.589A>G p.K197E | Missense Mutation (SNP) | VAF 68/401 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs774299095; called by muse, mutect2, varscan2
- HGD | c.549+1G>C p.X183_splice | Splice Site (SNP) | VAF 35/284 reads (12%) | catalogued as CS098253; called by muse, mutect2, varscan2
- HTR1A | c.812C>A p.A271D | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.081); catalogued as COSV100108995; called by muse, mutect2
- IL16 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 108/308 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs750770627; called by muse, mutect2, varscan2
- ITGB7 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99914176; called by muse, mutect2, varscan2
- ITIH6 | c.2012C>T p.S671F | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs763995265, COSV99513653; called by muse, mutect2, varscan2
- KBTBD13 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 80/223 reads (36%) | catalogued as rs766677668; called by muse, mutect2, varscan2
- KIAA1210 | c.3421C>T p.R1141W | Missense Mutation (SNP) | VAF 78/121 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs745577960, COSV101274165, COSV101274303, COSV68176979; called by muse, mutect2, varscan2
- KIF26A | c.3031C>T p.R1011W | Missense Mutation (SNP) | VAF 47/359 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1373498323, COSV100181010; called by muse, mutect2, varscan2
- KLHL32 | c.718A>G p.T240A | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100987426; called by muse, mutect2, varscan2
- LDHD | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1438427309; called by muse, mutect2, varscan2
- LRCH1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs776187583, COSV60844679; called by muse, mutect2, varscan2
- MAGEL2 | c.1133C>A p.T378K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV58566766; called by muse, mutect2, varscan2
- MRGPRX4 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs763831514, COSV58589662; called by muse, mutect2, varscan2
- MYO5A | c.3880A>G p.I1294V | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1162909820; called by muse, mutect2, varscan2
- NCKAP5L | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.159); catalogued as rs1452742971; called by muse, mutect2, varscan2
- NOTCH4 | c.5944C>G p.Q1982E | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs577160458, COSV66683978; called by muse, mutect2, varscan2
- OBSCN | c.7478G>T p.R2493L | Missense Mutation (SNP) | VAF 43/330 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV52789044; called by muse, mutect2, varscan2
- OR4C15 | c.790T>C p.F264L (on ENST00000314644; = p.F210L on NM_001001920.2) | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as COSV58952521; called by muse, mutect2, varscan2
- OR4N2 | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.774); catalogued as COSV100269987; called by muse, mutect2, varscan2
- OR5H1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV63402189; called by muse, mutect2, varscan2
- OR7E24 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV101509696; called by muse, mutect2, varscan2
- OR9G1 | c.742A>G p.T248A | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.533); catalogued as rs1001214740; called by muse, mutect2
- P3H2 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 58/600 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs904958070; called by muse, mutect2
- PHEX | c.23G>T p.S8I | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV65075924; called by muse, mutect2, varscan2
- POLD4 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs757680383; called by muse, mutect2
- PPP3R2 | c.117C>A p.S39R | Missense Mutation (SNP) | VAF 84/377 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as rs143999871; called by muse, mutect2, varscan2
- PRR12 | c.614C>T p.P205L (on ENST00000615927; = p.P1026L on NM_020719.3) | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as rs1189114781; called by muse, mutect2, varscan2
- PRR23B | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 70/724 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as COSV61493882; called by muse, mutect2
- PSD4 | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs765703151; called by muse, mutect2, varscan2
- RAB3GAP2 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424365; called by muse, mutect2
- RABEP1 | c.1798G>A p.V600I | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs368640006; called by muse, mutect2, varscan2
- RBFOX1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs139251660, COSV60977899; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF20 | c.2623G>A p.D875N | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs374721775; called by muse, mutect2, varscan2
- RNF213 | c.12638G>T p.R4213L | Missense Mutation (SNP) | VAF 182/547 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV60404946; called by muse, mutect2, varscan2
- RUBCNL | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV100529377; called by muse, mutect2, varscan2
- SAA1 | c.231C>A p.T77= | Splice Region (SNP) | VAF 34/112 reads (30%) | catalogued as COSV100736571; called by muse, mutect2
- SAMD15 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs369965792; called by muse, mutect2, varscan2
- SAMD9 | c.4069G>A p.D1357N | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs1222464630; called by muse, mutect2
- SETBP1 | c.2981A>T p.Y994F | Missense Mutation (SNP) | VAF 108/591 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99951470; called by muse, mutect2, varscan2
- SLC19A2 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 47/328 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52546076, COSV52546322; called by muse, mutect2, varscan2
- SLC35F4 | c.1103C>T p.T368I (on ENST00000339762 / NM_001352015.2; = p.T332I on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs1249930780; called by muse, mutect2, varscan2
- SLITRK2 | c.2157C>G p.S719R | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as rs1556945032; called by muse, mutect2, varscan2
- SOX1 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1343616771, COSV58378693; called by muse, mutect2, varscan2
- SRSF11 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1423468518, COSV63937515; called by muse, mutect2, varscan2
- STAT4 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs758109437, COSV61831529; called by muse, mutect2, varscan2
- SVEP1 | c.10283G>A p.R3428Q | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs201064336, COSV99929547; called by muse, mutect2, varscan2
- TACC2 | c.8063G>T p.R2688L (on ENST00000334433; = p.R766L on NM_006997.4) | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs760546620, COSV53286135; called by muse, mutect2, varscan2
- TENM1 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 65/101 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as rs765596962; called by muse, mutect2, varscan2
- TKTL1 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs139349276; called by muse, mutect2, varscan2
- TMEM161B | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376651198; called by muse, mutect2, varscan2
- TNFRSF11B | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 99/219 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs371566584, COSV99816854; called by muse, mutect2, varscan2
- TP53 | c.855G>T p.E285D | Missense Mutation (SNP) | VAF 403/688 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV52933457, COSV52950642; called by muse, mutect2, varscan2
- TRIM42 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 45/628 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53886095; called by muse, mutect2
- TRPM8 | c.2263G>A p.V755M | Missense Mutation (SNP) | VAF 55/516 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199991435, COSV100224350; called by muse, mutect2, varscan2
- TTN | c.11197G>A p.E3733K (on ENST00000591111; = p.E3687K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/163 reads (12%) | catalogued as rs1224727838; called by muse, mutect2, varscan2
- XIRP2 | c.2695G>T p.E899* (on ENST00000628543; = p.E1074* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV99738818; called by muse, mutect2, varscan2
- XIRP2 | c.9043G>T p.A3015S (on ENST00000628543; = p.A3190S on NM_152381.6) | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs765610945; called by muse, mutect2
- ZNF184 | c.1337A>G p.Y446C | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs561307011; called by muse, mutect2, varscan2
- ZNF208 | c.3476A>G p.H1159R | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs527278333; called by muse, mutect2, varscan2
- ZNF251 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs745350200; called by muse, mutect2, varscan2
- ZNF333 | c.1661G>T p.R554L | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV52884674; called by muse, mutect2, varscan2
- ZNF366 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 44/352 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs769814079, COSV100574055; called by muse, mutect2, varscan2
- ZNF385B | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 39/408 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.357); catalogued as COSV100416141, COSV61177946; called by muse, mutect2
- ZNF541 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs368317942; called by muse, mutect2, varscan2
- ZNF592 | c.3427A>G p.I1143V | Missense Mutation (SNP) | VAF 170/697 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs566303271; called by muse, mutect2, varscan2
- ZNF609 | c.1337C>G p.S446* | Nonsense Mutation (SNP) | VAF 41/397 reads (10%) | catalogued as COSV58582069; called by muse, mutect2, varscan2
- ABCB4 | c.3418G>A p.G1140R (on ENST00000265723 / NM_018849.3; = p.G1133R on NM_000443.4) | Missense Mutation (SNP) | VAF 58/471 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM20 | c.1284G>T p.Q428H | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ADAMTS3 | c.787G>T p.G263* | Nonsense Mutation (SNP) | VAF 99/316 reads (31%) | called by muse, mutect2, varscan2
- ADGRL2 | c.2394G>T p.M798I (on ENST00000370717 / NM_001366005.1; = p.M785I on NM_012302.4) | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- AFF2 | c.3800C>A p.T1267K | Missense Mutation (SNP) | VAF 54/80 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ANXA6 | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2
- ATF7IP | c.409G>C p.G137R | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2
- BDP1 | c.3986C>G p.S1329* | Nonsense Mutation (SNP) | VAF 15/198 reads (8%) | called by muse, mutect2
- BPIFB3 | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 62/341 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRINP1 | c.1271G>T p.R424L | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- BRINP2 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BSX | c.262+2T>A p.X88_splice | Splice Site (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- C11orf96 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2, varscan2
- C2CD3 | c.3119C>T p.S1040F | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.923); called by muse, mutect2
- C9orf78 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 96/323 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CC2D2A | c.4065T>A p.D1355E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.974); called by muse, mutect2
- CCDC141 | c.631C>G p.Q211E | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2
- CCDC151 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCPG1 | c.207del p.E70Kfs*45 | Frame Shift Del (DEL) | VAF 24/150 reads (16%) | called by mutect2, pindel, varscan2
- CDH11 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- CEP63 | c.1389G>T p.L463F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CEP70 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- CHAF1A | c.572G>C p.G191A | Missense Mutation (SNP) | VAF 131/331 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CHI3L2 | c.46G>T p.V16L | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2
- CLDN20 | c.89G>T p.W30L | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL27A1 | c.1732A>G p.R578G | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL4A4 | c.4732G>A p.V1578M | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CSE1L | c.2769C>A p.N923K | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CSMD3 | c.738A>T p.R246S | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CSNK1D | c.645dup p.L216Afs*14 | Frame Shift Ins (INS) | VAF 100/374 reads (27%) | called by mutect2, pindel, varscan2
- DCLRE1A | c.2292T>A p.H764Q | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DEPP1 | c.490A>T p.R164* | Nonsense Mutation (SNP) | VAF 57/175 reads (33%) | called by muse, mutect2, varscan2
- DMD | c.4514G>T p.C1505F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMRTB1 | c.426C>A p.S142R | Missense Mutation (SNP) | VAF 118/288 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJB8 | c.581T>A p.V194D | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- DOCK7 | c.3089A>G p.E1030G (on ENST00000635253 / NM_001367561.1; = p.E999G on NM_033407.3) | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2
- EDNRB | c.694A>G p.S232G (on ENST00000377211 / NM_001201397.1; = p.S142G on NM_000115.5) | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- EEF1A1 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- EFEMP1 | c.684C>A p.C228* | Nonsense Mutation (SNP) | VAF 20/242 reads (8%) | called by muse, mutect2
- EML5 | c.5445C>G p.I1815M (on ENST00000380664; = p.I1823M on NM_183387.3) | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- EYA4 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- EYA4 | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM171A1 | c.1732C>G p.L578V | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- FAM207A | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 95/436 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM83A | c.648+1G>T p.X216_splice | Splice Site (SNP) | VAF 42/107 reads (39%) | called by muse, mutect2, varscan2
- FHL5 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FMN1 | c.1492G>T p.A498S | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- FRAS1 | c.2295C>A p.C765* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | called by mutect2, varscan2
- GLE1 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 138/587 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- HECW1 | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HHIPL1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 133/289 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- IGLV5-45 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IGSF5 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ITGA11 | c.1518C>G p.F506L | Missense Mutation (SNP) | VAF 40/354 reads (11%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- KCTD12 | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KIF26A | c.5419G>T p.E1807* | Nonsense Mutation (SNP) | VAF 30/205 reads (15%) | called by muse, mutect2, varscan2
- KLHL32 | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 65/174 reads (37%) | called by muse, mutect2, varscan2
- LAMA2 | c.6430-1G>T p.X2144_splice | Splice Site (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- LRRC31 | c.29C>G p.S10* | Nonsense Mutation (SNP) | VAF 42/194 reads (22%) | called by muse, mutect2, varscan2
- LRRC52 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- LRRC7 | c.1609C>G p.L537V (on ENST00000651989 / NM_001370785.2; = p.L504V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by mutect2, varscan2
- LRRC7 | c.1718A>T p.Q573L (on ENST00000651989 / NM_001370785.2; = p.Q540L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MDGA2 | c.1154dup p.N387Kfs*30 (on ENST00000399232 / NM_001113498.2; = p.N89Kfs*30 on NM_182830.4) | Frame Shift Ins (INS) | VAF 16/111 reads (14%) | called by mutect2, pindel
- MPPED2 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- MS4A1 | c.474C>A p.H158Q | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- MS4A1 | c.476C>A p.T159K | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2
- MYO9B | c.1496A>G p.H499R | Missense Mutation (SNP) | VAF 15/345 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- MYO9B | c.5988C>G p.N1996K | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- NCF1 | c.966C>G p.D322E | Missense Mutation (SNP) | VAF 66/693 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NFKBIE | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NMRK2 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NSL1 | c.242A>G p.E81G | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by mutect2, varscan2
- NSMF | c.1084C>G p.P362A (on ENST00000371475 / NM_001130969.3; = p.P360A on NM_015537.4) | Missense Mutation (SNP) | VAF 162/461 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OBSCN | c.17521G>T p.A5841S | Missense Mutation (SNP) | VAF 77/298 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- OR13H1 | c.323C>A p.A108D | Missense Mutation (SNP) | VAF 64/105 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- OR4C16 | c.453T>A p.C151* | Nonsense Mutation (SNP) | VAF 39/108 reads (36%) | called by muse, mutect2, varscan2
- OR6V1 | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 15/322 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); called by muse, mutect2
- PDGFC | c.370T>G p.C124G | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PGM5 | c.1273T>C p.F425L | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PHLDB2 | c.3643T>C p.F1215L (on ENST00000393925 / NM_001134439.2; = p.F1172L on NM_145753.2) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- PIK3R1 | c.1567A>G p.R523G (on ENST00000521381 / NM_181523.3; = p.R253G on NM_181504.4) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, varscan2
- PNLIPRP1 | c.1344del p.Y448* | Frame Shift Del (DEL) | VAF 25/155 reads (16%) | called by mutect2, pindel, varscan2
- POLRMT | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 113/672 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- PROCR | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRPF38B | c.1169A>G p.K390R | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSD2 | c.896G>T p.S299I | Missense Mutation (SNP) | VAF 111/345 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- RARA | c.328-2A>T p.X110_splice | Splice Site (SNP) | VAF 59/178 reads (33%) | called by muse, mutect2, varscan2
- RDH16 | c.831_832dup p.R278Pfs*18 | Frame Shift Ins (INS) | VAF 57/366 reads (16%) | called by pindel, varscan2*
- RTN4IP1 | c.388T>A p.C130S | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- SEMA6A | c.2599G>C p.G867R | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SGCG | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC22A4 | c.370T>C p.Y124H | Missense Mutation (SNP) | VAF 139/576 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- SMARCAL1 | c.2014A>T p.R672W | Missense Mutation (SNP) | VAF 110/306 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- SRSF6 | c.191G>C p.R64P | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- TANGO6 | c.2212C>A p.Q738K | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- TARBP1 | c.3899T>A p.V1300E | Missense Mutation (SNP) | VAF 83/177 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TEAD4 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2
- TGM6 | c.983G>A p.S328N | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TMEM251 | c.280C>G p.Q94E (on ENST00000415050 / NM_001098621.4; = p.Q62E on NM_015676.3) | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNPO3 | c.2030C>G p.S677C | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.445); called by muse, mutect2
- TPP2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- TRGV3 | c.46A>T p.S16C | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TRIM55 | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TULP4 | c.1595A>G p.K532R | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- UBR1 | c.3619G>T p.V1207L | Missense Mutation (SNP) | VAF 139/391 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- USP34 | c.8462A>G p.Q2821R | Missense Mutation (SNP) | VAF 162/380 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- USP40 | c.3505C>G p.L1169V | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- VPS35L | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0.241); called by muse, mutect2
- VPS37D | c.228G>C p.E76D | Missense Mutation (SNP) | VAF 45/383 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF423 | c.952C>G p.L318V (on ENST00000563137 / NM_001379286.1; = p.L310V on NM_015069.4) | Missense Mutation (SNP) | VAF 115/541 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF493 | c.1007A>G p.E336G | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ZNF521 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF569 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD30B | c.519C>T p.L173= | Silent (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- ANO2 | c.1644C>A p.I548= (on ENST00000356134 / NM_001278597.3; = p.I552= on NM_001278596.3) | Silent (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2
- ANO5 | c.1845C>A p.T615= | Silent (SNP) | VAF 23/232 reads (10%) | called by muse, mutect2
- APBA2 | c.453C>A p.G151= | Silent (SNP) | VAF 223/647 reads (34%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.1023A>G p.V341= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as rs756574246; called by muse, mutect2, varscan2
- C9orf78 | c.159G>C p.L53= | Silent (SNP) | VAF 95/324 reads (29%) | called by muse, mutect2, varscan2
- CABS1 | c.1047A>G p.T349= | Silent (SNP) | VAF 26/99 reads (26%) | called by muse, mutect2, varscan2
- CDH24 | c.255G>C p.G85= | Silent (SNP) | VAF 33/138 reads (24%) | called by muse, mutect2, varscan2
- CELF5 | c.96C>T p.P32= | Silent (SNP) | VAF 123/361 reads (34%) | catalogued as rs940514000, COSV99486317; called by muse, mutect2, varscan2
- COL4A5 | c.3495A>G p.E1165= | Silent (SNP) | VAF 24/262 reads (9%) | catalogued as COSV60374529; called by muse, mutect2
- CPNE3 | c.33G>T p.L11= | Silent (SNP) | VAF 24/183 reads (13%) | called by muse, mutect2, varscan2
- CRACD | c.1030C>A p.R344= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- CTDP1 | c.921C>G p.V307= | Silent (SNP) | VAF 44/286 reads (15%) | called by muse, mutect2, varscan2
- CUBN | c.5904T>A p.G1968= | Silent (SNP) | VAF 61/166 reads (37%) | catalogued as rs754525566; called by muse, mutect2, varscan2
- CYP2A7 | c.129T>C p.I43= | Silent (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.1155C>A p.V385= | Silent (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- DLG5 | c.4422C>T p.D1474= | Silent (SNP) | VAF 22/191 reads (12%) | catalogued as rs537115951, COSV64948703; called by muse, mutect2, varscan2
- DYSF | c.81G>A p.V27= | Silent (SNP) | VAF 146/338 reads (43%) | called by muse, mutect2, varscan2
- EDNRB | c.693C>A p.A231= (on ENST00000377211 / NM_001201397.1; = p.A141= on NM_000115.5) | Silent (SNP) | VAF 58/178 reads (33%) | called by muse, mutect2, varscan2
- FAM102B | c.249C>T p.S83= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs763800417, COSV64240441; called by muse, mutect2, varscan2
- FBXL6 | c.228C>T p.S76= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- FMN2 | c.2223G>T p.A741= | Silent (SNP) | VAF 65/521 reads (12%) | catalogued as rs144753167; called by muse, mutect2, varscan2
- FNDC3B | c.24C>T p.T8= | Silent (SNP) | VAF 30/429 reads (7%) | catalogued as rs539042799, COSV100394909; called by muse, mutect2
- FOXI1 | c.882C>G p.P294= | Silent (SNP) | VAF 55/153 reads (36%) | called by muse, mutect2, varscan2
- GABRA6 | c.1224G>C p.S408= | Silent (SNP) | VAF 48/316 reads (15%) | catalogued as COSV50882107; called by muse, mutect2, varscan2
- GATM | c.375T>A p.A125= | Silent (SNP) | VAF 32/260 reads (12%) | called by muse, mutect2, varscan2
- GLP1R | c.594C>T p.D198= | Silent (SNP) | VAF 31/259 reads (12%) | catalogued as rs199745579; called by muse, mutect2, varscan2
- GP2 | c.612C>T p.N204= (on ENST00000381362 / NM_001007240.3; = p.N201= on NM_001502.4) | Silent (SNP) | VAF 24/214 reads (11%) | called by muse, mutect2, varscan2
- HBB | c.87G>T p.L29= | Silent (SNP) | VAF 138/336 reads (41%) | catalogued as rs1191121382; called by muse, mutect2, varscan2
- HNRNPUL2 | c.330G>T p.P110= | Silent (SNP) | VAF 52/172 reads (30%) | catalogued as rs1318223389, COSV53665329; called by muse, varscan2
- HOXA10 | c.1056G>A p.E352= | Silent (SNP) | VAF 35/160 reads (22%) | catalogued as COSV52228784; called by muse, mutect2, varscan2
- HTR1A | c.207C>T p.N69= | Silent (SNP) | VAF 61/481 reads (13%) | catalogued as COSV60502216; called by muse, mutect2, varscan2
- IGSF10 | c.3408G>T p.V1136= | Silent (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2, varscan2
- ITPR2 | c.4839G>A p.L1613= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV67270996; called by muse, mutect2, varscan2
- JMJD1C | c.4377C>T p.A1459= | Silent (SNP) | VAF 38/110 reads (35%) | called by muse, mutect2, varscan2
- MAPKAPK2 | c.132G>T p.P44= | Silent (SNP) | VAF 45/358 reads (13%) | catalogued as rs371879562; called by muse, mutect2, varscan2
- MCM8 | c.573G>A p.V191= | Silent (SNP) | VAF 21/113 reads (19%) | called by muse, mutect2, varscan2
- MUC17 | c.8010C>T p.T2670= | Silent (SNP) | VAF 42/160 reads (26%) | catalogued as rs947170340; called by muse, mutect2, varscan2
- MUC5B | c.8802G>A p.V2934= | Silent (SNP) | VAF 62/283 reads (22%) | catalogued as rs746131326, COSV101500117; called by muse, mutect2, varscan2
- MUC5B | c.10902G>A p.V3634= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV101499989; called by mutect2, varscan2
- MX1 | c.762A>G p.K254= | Silent (SNP) | VAF 42/263 reads (16%) | called by muse, mutect2, varscan2
- MYO9B | c.5157C>T p.L1719= | Silent (SNP) | VAF 123/270 reads (46%) | called by muse, mutect2, varscan2
- NPTX2 | c.729G>T p.T243= | Silent (SNP) | VAF 84/274 reads (31%) | catalogued as COSV55717249; called by muse, mutect2, varscan2
- OR56A4 | c.618G>C p.R206= | Silent (SNP) | VAF 66/156 reads (42%) | catalogued as COSV100417668; called by muse, mutect2, varscan2
- OR5F1 | c.522C>A p.I174= | Silent (SNP) | VAF 40/141 reads (28%) | called by muse, mutect2, varscan2
- PCDHA3 | c.147G>T p.A49= | Silent (SNP) | VAF 79/487 reads (16%) | catalogued as rs1388952872, COSV100973785, COSV65366629; called by muse, mutect2, varscan2
- PCDHA8 | c.2197C>A p.R733= | Silent (SNP) | VAF 64/315 reads (20%) | catalogued as COSV65326379; called by muse, mutect2, varscan2
- PCDHB4 | c.1929C>G p.V643= | Silent (SNP) | VAF 245/732 reads (33%) | called by muse, mutect2, varscan2
- PDE4B | c.774G>A p.L258= | Silent (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- PDZRN4 | c.120C>T p.S40= | Silent (SNP) | VAF 62/473 reads (13%) | called by muse, mutect2, varscan2
- PELI1 | c.933C>T p.C311= | Silent (SNP) | VAF 29/396 reads (7%) | catalogued as rs771996771, COSV62729824; called by muse, mutect2
- PRAMEF12 | c.471G>A p.T157= | Silent (SNP) | VAF 45/291 reads (15%) | catalogued as rs536167906, COSV100743436; called by muse, mutect2, varscan2
- PRUNE2 | c.4071A>G p.E1357= | Silent (SNP) | VAF 27/172 reads (16%) | called by muse, mutect2, varscan2
- RC3H1 | c.198G>A p.V66= | Silent (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- RGS20 | c.819G>A p.R273= (on ENST00000297313 / NM_170587.4; = p.R126= on NM_003702.4) | Silent (SNP) | VAF 97/218 reads (44%) | called by muse, mutect2, varscan2
- RHAG | c.555A>T p.V185= | Silent (SNP) | VAF 86/316 reads (27%) | called by muse, mutect2, varscan2
- ROR1 | c.45G>C p.A15= | Silent (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- RYR2 | c.8766C>A p.A2922= | Silent (SNP) | VAF 14/141 reads (10%) | called by muse, mutect2
- SEL1L2 | c.906T>A p.S302= | Silent (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- SKIL | c.1962C>G p.L654= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as rs374895091, COSV52062885; called by muse, mutect2
- SLITRK3 | c.255G>A p.Q85= | Silent (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- SPRYD7 | c.66G>A p.L22= | Silent (SNP) | VAF 32/244 reads (13%) | called by muse, mutect2, varscan2
- STAT1 | c.180C>A p.L60= | Silent (SNP) | VAF 54/347 reads (16%) | called by muse, mutect2, varscan2
- STYXL2 | c.2139G>A p.G713= | Silent (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- TBC1D30 | c.243G>A p.L81= | Silent (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- TRMT5 | c.348A>C p.A116= | Silent (SNP) | VAF 80/247 reads (32%) | called by muse, mutect2, varscan2
- TSPEAR | c.1905C>T p.V635= | Silent (SNP) | VAF 16/324 reads (5%) | catalogued as rs782448563; called by muse, mutect2
- TSPOAP1 | c.2517G>A p.A839= | Silent (SNP) | VAF 39/285 reads (14%) | catalogued as rs375185108; called by muse, mutect2, varscan2
- WDFY4 | c.2067C>T p.S689= | Silent (SNP) | VAF 37/219 reads (17%) | catalogued as rs535366458, COSV57425389; called by muse, mutect2, varscan2
- WFDC11 | c.6C>A p.V2= | Silent (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
- ZNF517 | c.759C>T p.R253= | Silent (SNP) | VAF 39/373 reads (10%) | catalogued as rs1161267155, COSV63464507; called by muse, mutect2, varscan2
- ZNF618 | c.882C>T p.D294= (on ENST00000374126 / NM_001318042.2; = p.D262= on NM_001318040.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/275 reads (10%) | called by muse, mutect2, varscan2
- ZNF679 | c.591A>G p.S197= | Silent (SNP) | VAF 28/115 reads (24%) | called by muse, mutect2, varscan2
- AC100826.1 | n.214C>G | RNA (SNP) | VAF 41/150 reads (27%) | called by muse, mutect2, varscan2
- ADAM20P1 | n.1116G>C | RNA (SNP) | VAF 27/153 reads (18%) | called by muse, mutect2, varscan2
- ADAM9 | c.-90G>T | 5'UTR (SNP) | VAF 48/404 reads (12%) | called by muse, mutect2, varscan2
- ADD2 | c.1593+31del | Intron (DEL) | VAF 20/177 reads (11%) | catalogued as COSV52455020; called by mutect2, pindel, varscan2
- AIFM1 | c.249+18G>A | Intron (SNP) | VAF 94/146 reads (64%) | catalogued as rs765995039; called by muse, mutect2, varscan2
- AK2 | c.*2919G>T | 3'UTR (SNP) | VAF 46/231 reads (20%) | called by muse, mutect2, varscan2
- ANXA10 | c.-29C>T | 5'UTR (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- BTBD7 | c.1162+5274G>A | Intron (SNP) | VAF 18/322 reads (6%) | called by muse, mutect2
- CHMP2B | c.321+11G>A | Intron (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- EYS | c.1767-6788G>A | Intron (SNP) | VAF 64/410 reads (16%) | catalogued as rs1014571682; called by muse, mutect2, varscan2
- GABRG2 | c.1248+303G>T | Intron (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- HDAC3 | c.691+29C>T | Intron (SNP) | VAF 10/262 reads (4%) | called by muse, mutect2
- HPD | c.93+10G>A | Intron (SNP) | VAF 61/548 reads (11%) | catalogued as rs755545913; called by muse, mutect2, varscan2
- KCNC3 | chr19:50333849 del G | 5'Flank (DEL) | VAF 62/172 reads (36%) | called by mutect2, pindel
- KIAA1958 | c.1172-27139T>C | Intron (SNP) | VAF 45/196 reads (23%) | called by muse, mutect2, varscan2
- LINC02551 | n.1184T>C | RNA (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- MDM4 | c.412-220G>A | Intron (SNP) | VAF 29/155 reads (19%) | called by muse, mutect2, varscan2
- MED24 | c.1531-15dup | Intron (INS) | VAF 85/324 reads (26%) | called by mutect2, pindel, varscan2
- MIR34A | n.82C>T | RNA (SNP) | VAF 74/442 reads (17%) | called by muse, mutect2, varscan2
- MST1L | n.289C>T | RNA (SNP) | VAF 74/896 reads (8%) | catalogued as rs565699313; called by muse, mutect2
- MYOCD | c.2059-1569G>T | Intron (SNP) | VAF 80/239 reads (33%) | catalogued as COSV58497713; called by muse, mutect2, varscan2
- ORC6 | chr16:46689184 del C | 5'Flank (DEL) | VAF 26/119 reads (22%) | called by mutect2, pindel, varscan2
- PPP5D1 | n.674C>A | RNA (SNP) | VAF 39/92 reads (42%) | called by muse, mutect2, varscan2
- PPP5D1 | n.446C>T | RNA (SNP) | VAF 35/202 reads (17%) | catalogued as rs778347076; called by muse, mutect2, varscan2
- RAB37 | chr17:74737047 T>G | 5'Flank (SNP) | VAF 85/275 reads (31%) | called by muse, mutect2, varscan2
- RFK | chr9:76399019 C>A | 5'Flank (SNP) | VAF 84/690 reads (12%) | called by muse, mutect2, varscan2
- SIGLEC14 | c.*44C>T | 3'UTR (SNP) | VAF 22/303 reads (7%) | catalogued as COSV99707111; called by muse, mutect2
- SLC9B1P1 | n.656C>G | RNA (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- TMCO1 | c.*416_*417insG | 3'UTR (INS) | VAF 43/139 reads (31%) | catalogued as rs1558026805; called by mutect2, pindel, varscan2
